Gene-level copy-number profile of tumor specimen AP-8PRJ-JA from APOLLO case AP-8PRJ, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen AP-8PRJ-JA: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7023bb89-029e-4238-bbb6-4d1921821230.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-8PRJ-DK (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/c3559fd1-077b-48d8-9d58-419950270b90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,767; copy number 2: 34,292; copy number 3: 14,572; copy number 4: 2,782; copy number 5: 577; copy number 6: 377; copy number 7: 26.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,862,672–5,862,741, 1 gene: MIR4689.
- chr8:7,926,337–7,952,413, 2 genes: ZNF705B, DEFB108A.
- chr8:7,967,344–7,968,544, 1 gene (within-gene range 0–2): AC130365.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 980 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–56,448,375, 958 genes, copy number 5–7 (broad region; genes not listed).
- chr15:35,181,799–36,818,459, 21 genes, copy number 5: ANP32AP1, DPH6, NUTF2P6, RBM17P4, MIR3942, AC019288.1, HNRNPA1P45, DPH6-DT, AC068867.1, LINC02853, MIR4510, AC021351.1, AC087516.1, AC087516.2, COX6CP4, CDIN1, AC103988.1, LARP4P, TPST2P1, AC013640.1, CSNK1A1P1.
- chr16:16,541,217–16,541,847, 1 gene, copy number 5: AC136619.2.

Autosomal genes at a single copy (total copy number 1): 5,282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
